Somatic mutation profile of tumor specimen TCGA-XF-AAMZ-01A (aliquot TCGA-XF-AAMZ-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 81.2 years (29,667 days).
Specimen TCGA-XF-AAMZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189ff07e-eb3a-49fa-a47f-83491d19b030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMZ-10A (Blood Derived Normal), aliquot TCGA-XF-AAMZ-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcad4ce5-cbc2-4b74-892f-78c82ae70ced

The open-access MAF lists 259 somatic variants for this specimen: 206 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 49, Nonsense Mutation 18, 3'UTR 2, Frame Shift Ins 2, Splice Region 1, RNA 1, Nonstop Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHDDS | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs1229969030, COSV52575269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV60619878, COSV60622258; called by muse, mutect2, varscan2
- AC005324.2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100372129; called by muse, mutect2
- ACAP1 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV50134134; called by muse, varscan2
- ADAMTS3 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.96); catalogued as COSV54385422; called by muse, mutect2
- ADGRB3 | c.3810G>C p.L1270F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53235162; called by muse, mutect2
- ADGRE2 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100216277, COSV59691793; called by muse, mutect2, varscan2
- ADNP | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.137); catalogued as COSV62424525; called by muse, mutect2
- ADRB1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV65168241; called by muse, mutect2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2
- AKR1E2 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100033703; called by muse, mutect2, varscan2
- ANKRD28 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.035); catalogued as COSV67516959; called by muse, mutect2
- ANO5 | c.2700G>C p.M900I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV61082221; called by muse, mutect2, varscan2
- AP1G2 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1364814975, COSV55337393; called by muse, mutect2, varscan2
- AP2M1 | c.1190C>G p.S397C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53047096; called by muse, mutect2
- ARHGEF11 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV59352474; called by muse, mutect2
- ATP13A3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as rs369995803; called by muse, mutect2, varscan2
- BCO1 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV50728078; called by muse, mutect2, varscan2
- BLM | c.2729G>C p.R910T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs1567053290, COSV61921835; ClinVar: uncertain significance; called by muse, varscan2
- C1orf87 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100967279; called by muse, mutect2, varscan2
- C20orf27 | c.315G>T p.K105N (on ENST00000379772 / NM_001258429.2; = p.K130N on NM_001039140.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV53923210; called by muse, mutect2, varscan2
- CACNA1F | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.228); catalogued as COSV59903116; called by muse, mutect2, varscan2
- CACNA2D1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV62373094; called by muse, mutect2, varscan2
- CCDC96 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV100028141; called by muse, mutect2
- CDKAL1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs747005469, COSV51179700; called by muse, mutect2, varscan2
- CEP170 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV60506236; called by muse, mutect2, varscan2
- CEP350 | c.2289G>C p.L763F | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62598924; called by muse, mutect2
- CFAP43 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs989014992, COSV53376348; called by muse, mutect2, varscan2
- CFAP61 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55619907, COSV55652253; called by muse, mutect2
- CHIA | c.365C>T p.S122L (on ENST00000343320; = p.S14L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58473800; called by muse, mutect2, varscan2
- CLIP3 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV62111716; called by muse, mutect2, varscan2
- COPS3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV52004268; called by muse, mutect2, varscan2
- CSMD3 | c.1993G>A p.G665S (on ENST00000297405 / NM_001363185.1; = p.G561S on NM_052900.3) | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV52106949, COSV52310826; called by muse, mutect2
- CTNND2 | c.459G>C p.Q153H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); catalogued as COSV100475128, COSV100481595; called by muse, mutect2
- CYP2C18 | c.600A>T p.K200N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV53669776; called by muse, mutect2, varscan2
- DCAF8 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1334652694, COSV58782728, COSV58783603; called by muse, mutect2, varscan2
- DDX20 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV63830775; called by muse, mutect2, varscan2
- DHX35 | c.607C>G p.R203G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52667561, COSV99327035; called by muse, mutect2
- DHX38 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1404402633, COSV51696328; called by muse, mutect2
- DIPK2B | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | catalogued as COSV100933505; called by muse, mutect2, varscan2
- DNAH11 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs745389124, COSV60940833; called by muse, mutect2, varscan2
- DSP | c.3703C>G p.L1235V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV65791218; called by muse, mutect2, varscan2
- DYSF | c.2730G>T p.K910N | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV50269526; called by muse, mutect2, varscan2
- E2F4 | c.1228G>C p.V410L | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV62605906; called by muse, mutect2
- EGR4 | c.1558C>T p.R520C (on ENST00000545030; = p.R417C on NM_001965.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771686012, COSV71531902; called by muse, mutect2, varscan2
- ELAPOR2 | c.1469A>G p.N490S (on ENST00000450689 / NM_001142749.3; = p.N323S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as rs961242711, COSV51884191; called by muse, mutect2, varscan2
- EPHB3 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777166808, COSV57804299, COSV57806631; called by muse, mutect2, varscan2
- ERCC6L | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV57819428; called by muse, mutect2
- ESRRG | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63150534; called by muse, mutect2, varscan2
- FASTKD5 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53904268; called by muse, mutect2
- FBLIM1 | c.885C>G p.F295L | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60028651; called by muse, mutect2
- FBXO34 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV58253400, COSV58254120; called by muse, mutect2, varscan2
- FGD2 | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236767; called by muse, mutect2
- FRMD5 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.353); catalogued as rs558094412, COSV68720463; called by muse, mutect2, varscan2
- FRMD7 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs748910947, COSV53744690; called by muse, mutect2, varscan2
- FXYD4 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.782); catalogued as COSV72052621; called by muse, mutect2, varscan2
- GAK | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100034174; called by muse, mutect2
- GALNT14 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100205758; called by muse, mutect2
- GLRA3 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56857987; called by muse, mutect2, varscan2
- GMPPB | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs756662069, COSV57537543; called by muse, mutect2, varscan2
- GNAQ | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs2013373, COSV54107408; called by muse, mutect2, varscan2
- GNAT3 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68067925; called by muse, mutect2, varscan2
- GNL3L | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs145095477, COSV100328191; called by muse, mutect2
- GON4L | c.4988C>T p.T1663I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as COSV55187190; called by muse, mutect2, varscan2
- GPR161 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs1306019071, COSV54787857; called by muse, mutect2, varscan2
- HLA-DPA1 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV70088315; called by muse, mutect2
- IKBKE | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV100898401; called by muse, mutect2
- IL21 | c.420C>G p.F140L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52645487, COSV52646855; called by muse, mutect2, varscan2
- IL27RA | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs374053127; called by muse, mutect2, varscan2
- IL7R | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV100286734; called by muse, mutect2
- IQGAP1 | c.2464C>T p.R822* | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV99185418; called by muse, mutect2
- KANSL1 | c.2707G>A p.E903K (on ENST00000574590 / NM_001193465.2; = p.E904K on NM_015443.4) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52265208; called by muse, mutect2
- KDM5B | c.2437G>C p.V813L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV52504448; called by muse, mutect2, varscan2
- KHDRBS1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56980752; called by muse, mutect2
- KHDRBS1 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV56980762; called by muse, mutect2, varscan2
- KIAA1549 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs778018617, COSV54306017; called by muse, varscan2
- KIDINS220 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56750597; called by muse, mutect2, varscan2
- KIF15 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV58158074, COSV58158532; called by muse, mutect2, varscan2
- LAD1 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.393); catalogued as COSV66212060; called by muse, mutect2
- LANCL2 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV54647652; called by muse, mutect2, varscan2
- LPAR4 | c.872T>G p.I291S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV70912227; called by muse, mutect2
- LRP6 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53783563, COSV53785994; called by muse, mutect2
- LRRC8B | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.655); catalogued as COSV58373161; called by muse, mutect2
- LRRC8C | c.2168A>C p.D723A | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV64995416; called by muse, mutect2, varscan2
- LRRN3 | c.1757C>G p.S586* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100074111; called by muse, mutect2, varscan2
- LY9 | c.1334T>A p.I445N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as rs781339491, COSV54431643; called by muse, mutect2, varscan2
- MAP3K20 | c.1873C>G p.Q625E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); catalogued as COSV64377230; called by muse, mutect2
- MARK1 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV65065667, COSV65067560; called by muse, mutect2
- MCM10 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66333119; called by muse, varscan2
- MCM10 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as COSV66333145; called by muse, varscan2
- MEA1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99775915; called by muse, mutect2, varscan2
- MED12 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV61332231; called by muse, mutect2
- MIB1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV55087966; called by muse, mutect2, varscan2
- MKNK1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57860495; called by muse, mutect2, varscan2
- MORC3 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101265088; called by muse, mutect2
- MTHFS | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV51912948; called by muse, mutect2, varscan2
- MYO9A | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61847782; called by muse, mutect2, varscan2
- MYOCD | c.2553C>G p.F851L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1324418749, COSV58497519, COSV58498235; called by muse, mutect2, varscan2
- N4BP2L2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57227418; called by muse, mutect2, varscan2
- NBEAL2 | c.7865G>A p.R2622H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1299423017, COSV52754335; called by muse, mutect2, varscan2
- NEUROD6 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV51770092, COSV51770198; called by muse, mutect2, varscan2
- NKAPD1 | c.727G>T p.E243* (on ENST00000280352 / NM_001082970.2; = p.E244* on NM_018195.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99736744; called by muse, mutect2, varscan2
- NPFFR2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs766685613, COSV58146485; called by muse, mutect2
- NRK | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV54590213; called by muse, mutect2
- OFD1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV60794325; called by mutect2, varscan2
- OR2J3 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV65848668; called by muse, mutect2, varscan2
- OR4K5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151215030; called by muse, varscan2
- OR4N2 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1354803448, COSV60050055, COSV60050839; called by muse, mutect2, varscan2
- OR6F1 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV57466850; called by muse, mutect2, varscan2
- OR9Q2 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV100285566; called by muse, mutect2
- OXNAD1 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99551520; called by muse, mutect2
- PBRM1 | c.3123G>A p.K1041= (on ENST00000296302 / NM_001366071.2; = p.K1016= on NM_018313.5) | Splice Region (SNP) | VAF 7/67 reads (10%) | catalogued as COSV56261817, COSV56272921; called by muse, mutect2
- PCDHA2 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364767; called by muse, mutect2, varscan2
- PCDHB8 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as COSV50754429; called by muse, mutect2, varscan2
- PCDHGA7 | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV53944953, COSV99548639; called by muse, mutect2
- PDIA5 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1364489740, COSV60246883; called by muse, mutect2
- PGAM4 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV58442939; called by muse, mutect2
- PHKA1 | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs140865522, COSV59801883; called by muse, mutect2, varscan2
- PHYHD1 | c.547G>C p.E183Q (on ENST00000372592 / NM_001100876.2; = p.W175C on NM_174933.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV58279904; called by muse, mutect2, varscan2
- PI4KA | c.5092G>C p.D1698H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55404405; called by muse, mutect2, varscan2
- PLEKHG7 | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 11/127 reads (9%) | catalogued as rs368328583; called by muse, mutect2
- PMFBP1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 52/297 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs781341509, COSV52821009, COSV52828160; called by muse, mutect2, varscan2
- PNLIPRP3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV65047996; called by muse, mutect2, varscan2
- PPIG | c.2161G>C p.E721Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV53641358; called by muse, mutect2
- PPIL6 | c.935G>C p.*312Sext*8 | Nonstop Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101446777; called by muse, mutect2, varscan2
- PPP1R13B | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV52448852; called by muse, mutect2, varscan2
- PRC1 | c.6G>C p.R2S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV60979077; called by muse, mutect2, varscan2
- PYGB | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV53815914; called by muse, mutect2, varscan2
- RANBP17 | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV66644753; called by muse, mutect2
- RANBP6 | c.3245T>A p.L1082* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99424479; called by muse, mutect2, varscan2
- RARRES1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV52961534; called by muse, mutect2, varscan2
- RBM43 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV58878126; called by muse, mutect2
- REP15 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.93); catalogued as COSV57287834; called by muse, mutect2
- RFLNB | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61239994; called by muse, mutect2
- RGS3 | c.1989G>C p.E663D (on ENST00000350696 / NM_001282923.2; = p.E551D on NM_017790.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as COSV58277175; called by muse, mutect2, varscan2
- RHBDD1 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100392283; called by muse, mutect2
- RIF1 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99691381; called by muse, mutect2
- RIF1 | c.6683C>A p.S2228Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV54612593; called by muse, mutect2, varscan2
- RIPK4 | c.1064dup p.E356Gfs*21 (on ENST00000352483; = p.E308Gfs*21 on NM_020639.3) | Frame Shift Ins (INS) | VAF 22/102 reads (22%) | catalogued as rs746595711; called by mutect2, pindel, varscan2
- RSL1D1 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs375088154; called by muse, mutect2
- SACS | c.13268C>T p.S4423L | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV66534712; called by muse, mutect2
- SECISBP2 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776028065, COSV59391076; called by muse, mutect2, varscan2
- SEZ6 | c.2327A>G p.D776G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.681); catalogued as COSV100253639; called by muse, mutect2
- SH2D1B | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV63391979; called by muse, mutect2
- SH3KBP1 | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as rs1191460724, COSV101115679, COSV101116442; called by muse, mutect2, varscan2
- SLC10A3 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV54835607; called by muse, mutect2, varscan2
- SLC22A13 | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV61290301; called by muse, mutect2, varscan2
- SMOX | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV53863092; called by muse, mutect2, varscan2
- SNCB | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100031383; called by muse, mutect2
- SRCAP | c.6679G>A p.E2227K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV52667731, COSV99049146; called by muse, mutect2, varscan2
- ST8SIA4 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | PolyPhen probably damaging (0.996); catalogued as COSV51506333; called by muse, mutect2, varscan2
- SYCP2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs767459620, COSV62765955; called by muse, mutect2, varscan2
- TCHH | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs750827061, COSV64273008; called by muse, mutect2, varscan2
- TENM3 | c.5659G>C p.D1887H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1482945789, COSV69299750, COSV69315172; called by muse, mutect2
- TEX2 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99367580; called by muse, mutect2
- TMEM196 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV101337540, COSV68254088; called by muse, mutect2, varscan2
- TNC | c.3099A>T p.R1033S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV60780742; called by muse, mutect2, varscan2
- TNFAIP6 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54639903; called by muse, mutect2
- TNS1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs976031308, COSV50691216; called by muse, mutect2
- TNS2 | c.2765A>G p.E922G (on ENST00000314250 / NM_170754.4; = p.E932G on NM_015319.2) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV56852393; called by muse, mutect2, varscan2
- TOGARAM2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV65419926; called by muse, mutect2
- TOR1B | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1486116328, COSV52212365; called by muse, mutect2, varscan2
- TRIM10 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64998131; called by muse, mutect2, varscan2
- TTN | c.85297G>T p.E28433* (on ENST00000591111; = p.E21009* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100633798, COSV59956732; called by muse, mutect2, varscan2
- TTN | c.4802A>T p.Y1601F (on ENST00000591111; = p.Y1555F on NM_003319.4) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | PolyPhen benign (0.009); catalogued as COSV59896872; called by muse, mutect2, varscan2
- TXNDC2 | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV60152065; called by muse, varscan2
- UBL4A | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557212699, COSV54835598; called by muse, mutect2, varscan2
- UBR4 | c.7426G>C p.E2476Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64382688; called by muse, mutect2, varscan2
- UBR4 | c.6505G>C p.E2169Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64383073; called by muse, mutect2, varscan2
- UMPS | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1375993395, COSV51736273; called by muse, mutect2, varscan2
- VPS35 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.942); catalogued as COSV54476993; called by muse, mutect2, varscan2
- VPS8 | c.3485C>T p.P1162L (on ENST00000625842 / NM_001349294.1; = p.P1160L on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99804281; called by muse, mutect2
- VSIG10 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as rs1292293162, COSV100821381; called by muse, mutect2
- VSTM2L | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs751853698, COSV65095568; called by muse, mutect2, varscan2
- WAPL | c.1460C>G p.S487C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs1259963362, COSV53932481; called by muse, mutect2, varscan2
- WASHC4 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59888528; called by muse, mutect2, varscan2
- WDFY3 | c.4732C>T p.P1578S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs867951575, COSV55693757; called by muse, mutect2, varscan2
- WDR11 | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.838); catalogued as COSV54785542; called by muse, mutect2
- WDR25 | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV58934041; called by muse, mutect2, varscan2
- YARS1 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV65113060, COSV65115067; called by muse, mutect2
- YEATS2 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59361661; called by muse, mutect2
- ZBTB41 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV66358704; called by muse, mutect2, varscan2
- ZBTB41 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV66358710; called by muse, mutect2
- ZBTB8A | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs1172959679, COSV57141603; called by muse, mutect2
- ZNF135 | c.633G>C p.E211D (on ENST00000313434 / NM_001289401.2; = p.E223D on NM_003436.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); catalogued as COSV57880220; called by muse, mutect2, varscan2
- ZNF154 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs369809366; called by muse, mutect2, varscan2
- ZNF197 | c.2429G>C p.R810T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60359907, COSV60360109; called by muse, mutect2
- ZNF236 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs766500139, COSV53482643; called by mutect2, varscan2
- ZNF362 | c.1179C>G p.H393Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65031077; called by muse, mutect2
- ZNF45 | c.877del p.V293Ffs*3 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | catalogued as COSV54192441; called by mutect2, pindel, varscan2
- ZNF484 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776341612, COSV60256545; called by muse, mutect2, varscan2
- ZNF582 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV56731341; called by muse, mutect2
- ZNF654 | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV58804951; called by muse, mutect2, varscan2
- ZNF655 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755234889, COSV53158062; called by muse, mutect2, varscan2
- ZNF662 | c.1139G>C p.R380T | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377755545, COSV60240890, COSV60241072; called by muse, mutect2
- ZNF667 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52631332; called by muse, mutect2, varscan2
- ZNF709 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as COSV67194183; called by muse, mutect2
- ZNF780B | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV55461845; called by muse, mutect2
- ZNF808 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV63118721; called by muse, mutect2
- ZP2 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV99559901; called by muse, mutect2
- ZSCAN22 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV61638670; called by muse, mutect2, varscan2
- ZSCAN22 | c.1126G>T p.G376W | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61638676; called by muse, mutect2, varscan2
- C1GALT1C1L | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2
- IGHG3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- OR8G2P | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- WRN | c.3024_3030dup p.T1011Gfs*17 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | called by mutect2, varscan2
- AKAP9 | c.11217C>T p.L3739= (on ENST00000359028; = p.L3715= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs1481644748, COSV62339004; called by muse, mutect2, varscan2
- AMER1 | c.1209T>C p.D403= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57655201; called by muse, mutect2, varscan2
- APLNR | c.357C>T p.C119= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99951705; called by muse, mutect2
- C20orf194 | c.216A>G p.L72= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as rs775567564, COSV52691689; called by muse, mutect2
- CFAP65 | c.3984A>C p.S1328= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV58558107; called by muse, mutect2
- CPT1A | c.2082G>T p.V694= | Silent (SNP) | VAF 48/274 reads (18%) | catalogued as COSV99681669; called by muse, mutect2
- CREG2 | c.621C>T p.I207= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1468413889, COSV61317878; called by muse, mutect2
- CTSZ | c.267C>T p.C89= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs769000655, COSV99413758; called by muse, mutect2, varscan2
- DCP1B | c.1131C>G p.A377= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV54967305; called by muse, mutect2, varscan2
- DDHD2 | c.177C>T p.F59= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV101240662; called by muse, mutect2
- DEPTOR | c.669G>A p.R223= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV53812781; called by muse, mutect2, varscan2
- EFCAB12 | c.534G>A p.Q178= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1203461873, COSV100394867; called by muse, mutect2
- EMC4 | c.384G>A p.Q128= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV50784489; called by muse, mutect2, varscan2
- ENPP2 | c.984T>C p.P328= (on ENST00000075322 / NM_001040092.3; = p.P380= on NM_006209.5) | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as COSV50010112; called by muse, mutect2
- FAT4 | c.14217C>A p.T4739= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV58672227; called by muse, mutect2, varscan2
- FZD8 | c.1536G>A p.S512= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1290191206, COSV65967526; called by muse, mutect2
- GOLGA1 | c.1770G>C p.S590= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV63024119; called by muse, mutect2
- GOLGB1 | c.9090C>G p.L3030= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV61461964; called by muse, mutect2
- GOLGB1 | c.9003C>G p.L3001= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1451717131, COSV61461974; called by muse, mutect2
- GPR50 | c.351C>T p.F117= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV54437116; called by muse, mutect2, varscan2
- GRIA1 | c.768G>A p.V256= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV53589696; called by muse, mutect2
- GRIK2 | c.681C>A p.I227= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV59713338; called by muse, mutect2, varscan2
- HDAC6 | c.2245C>T p.L749= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV61927556; called by muse, mutect2, varscan2
- KIAA0513 | c.789C>T p.D263= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs772769000, COSV50740612; called by muse, varscan2
- KIF21A | c.1200C>T p.L400= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV62767461, COSV62774912; called by muse, mutect2
- KLF6 | c.312G>A p.L104= | Silent (SNP) | VAF 16/279 reads (6%) | catalogued as COSV51493745; called by muse, mutect2
- LCN12 | c.186C>T p.N62= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs372683477; called by muse, mutect2, varscan2
- NEFM | c.144G>A p.V48= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55330457, COSV99647289; called by muse, mutect2, varscan2
- OR6F1 | c.702G>T p.R234= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV57466841; called by muse, mutect2
- PCDHGA12 | c.1194C>T p.Y398= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs188338684, COSV52742606; called by muse, mutect2, varscan2
- PCDHGB4 | c.813G>A p.E271= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV53902062; called by muse, mutect2
- POMGNT1 | c.1473C>T p.I491= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100915826; called by muse, mutect2
- PRAMEF20 | c.1311G>A p.L437= | Silent (SNP) | VAF 73/306 reads (24%) | called by muse, mutect2, varscan2
- PTOV1 | c.639C>T p.I213= | Silent (SNP) | VAF 20/213 reads (9%) | catalogued as rs1046596920, COSV55586361; called by muse, mutect2
- RFX7 | c.1434A>T p.T478= (on ENST00000559447 / NM_001368074.1; = p.T575= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100429526; called by muse, mutect2
- SCGB2A1 | c.222G>C p.L74= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV55275703, COSV55276291; called by muse, mutect2, varscan2
- SH3BP5 | c.642C>T p.L214= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV53742983; called by muse, mutect2, varscan2
- SLC16A7 | c.843G>T p.S281= | Silent (SNP) | VAF 10/149 reads (7%) | catalogued as COSV53892256; called by muse, mutect2
- SLC23A2 | c.1755G>A p.K585= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV100595373; called by muse, mutect2
- SLC24A2 | c.1212G>A p.G404= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV53857947; called by muse, mutect2
- TCF25 | c.1158C>T p.I386= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs774329898, COSV54524505; called by muse, mutect2, varscan2
- TET3 | c.4920G>T p.S1640= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV69640785; called by muse, mutect2, varscan2
- TIAM1 | c.1350G>A p.K450= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV54538435; called by muse, mutect2
- TTLL12 | c.687G>C p.L229= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53354204, COSV53354888; called by muse, mutect2, varscan2
- USP17L2 | c.495C>G p.L165= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs767306650; called by muse, mutect2
- USP9X | c.4677G>C p.L1559= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV61066229, COSV61066916; called by muse, mutect2
- ZFHX3 | c.5388C>A p.L1796= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1476137598, COSV51709113; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.837G>C p.L279= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs1362337846, COSV58672510; called by muse, mutect2, varscan2
- ZSCAN1 | c.546C>A p.L182= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1350567118, COSV56601891, COSV99991927; called by muse, mutect2, varscan2
- CPLANE1 | c.*4049C>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as COSV57052606; called by muse, varscan2
- MORF4 | n.387C>T | RNA (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- NMT2 | c.-1G>A | 5'UTR (SNP) | VAF 4/43 reads (9%) | catalogued as rs1333370150, COSV100975493, COSV65382244; called by muse, mutect2
- TMEM107 | c.*747G>A | 3'UTR (SNP) | VAF 8/59 reads (14%) | catalogued as rs529248650, COSV100328850; called by muse, mutect2, varscan2
